TCGA case TCGA-HM-A6W2 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Ovary; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/929505f7-0270-475e-a9d6-00bf38dc78ba

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 35.0 years (12,775 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M1; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 7; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 85 days; Days to treatment end: 120 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 85 days; Days to treatment end: 120 days; Treatment dose: 4,500 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Chemo concurrent to radiation: Yes; Prescribed dose: 70; Prescribed dose units: mg; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (10 entries)
- Day 9 (preoperative): Days to imaging: 9 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 9 (preoperative): Days to imaging: 9 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 28 (preoperative): ECOG performance status: 0.
- Day 62 (preoperative): Days to imaging: 62 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 62 (preoperative): Days to imaging: 62 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 62 (preoperative): Days to imaging: 62 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 62 (preoperative): Days to imaging: 62 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 62 (preoperative): Days to imaging: 62 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Days to follow up: 287 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 125.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 160 cm; BMI: 34.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 8; Age at onset: 27.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HM-A6W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,280 mg.
  Slide TCGA-HM-A6W2-01A-02-TS2: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-HM-A6W2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HM-A6W2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 1,340 mg.
  Slide TCGA-HM-A6W2-06A-02-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-HM-A6W2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Live birth pregnancy count: 2; Total pregnancy count: 2; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Adenosquamous; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Pelvic extension comment: Metastases to Right Ovary; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Days to ct scan ab pelvis: 9; New tumor event diagnosis indicator: No.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent.
- Treatment, Radiation therapy info: Radiation therapy xrt type: Imrt.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 70mg; Chemo concurrent fractions total: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 287 days; disease-specific survival: no event (censored), 287 days; progression-free interval: no event (censored), 287 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HM-A6W2-01A-21D-A33N-01): tumor purity 0.85, ploidy 2.02, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HM-A6W2-06A-22D-A33N-01): tumor purity 0.89, ploidy 1.97, whole-genome doublings 0.
